Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4963, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4963-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-4963

Clinical Diagnosis & History:

with left renal mass.

Specimens Submitted:

1: Kidney and adrenal. left, nephrectomy and adrenalectomy

DIAGNOSIS:

1. Kidney and adrenal. left, nephrectomy and adrenalectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 6.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Tumor abuts the renal sinus fat

Renal Vein Invasion:

Not Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	deep

Gross Description:

1). The specimen is received fresh labeled "left kidney and adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 349 g in total. The kidney measures 12.0 x 5.6 x 3.7 cm. The attached ureter measures 4.0 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.6 cm in length and 0.6 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified, measuring 6.5 x 1.6 x 0.4 cm. The kidney is inked black and bivalved to reveal a well-circumscribed yellow variegated mass with central scar abutting the capsule located in the superior pole measuring 6.5 x 5.9 x 4.0 cm. The lesion extend inferiorly to compress the renal pelvis, and does not appear to involve the sinus fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC--frozen section control

UVM -- ureteral and vessel margins

T-- tumor

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

AD -- adrenal gland

Summary of Sections:

Part 1: Kidney and adrenal. left, nephrectomy and adrenalectomy

Block	Sect. Site	PCs
2	ad	2
1	fsc	1
1	k	1
1	rp	1
4	t	4
2	tk	2
1	tsf	1
1	uvm	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA, CONVENTIONAL TYPE
PERMANENT DIAGNOSIS:

Source: NCI Genomic Data Commons file 91b74594-3846-4aa1-bcff-04896fb8022e (TCGA-BP-4963.779571C1-328F-4ABA-B77A-069283513E0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).